Somatic mutation profile of tumor specimen 241c8dec-b317-4794-8cc2-07c14c (aliquot 241c8dec-b317-4794-8cc2-07c14c_D6_1) from CPTAC case 11BR017, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 74.7 years (27,283 days).
Specimen 241c8dec-b317-4794-8cc2-07c14c: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23b56fe7-114c-471e-bbc5-6dcb763fff51.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen e324df92-19fa-41f1-bf90-638803 (Blood Derived Normal), aliquot e324df92-19fa-41f1-bf90-638803_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3990fdd3-884a-41ef-a553-55a76fa3547c

The open-access MAF lists 56 somatic variants for this specimen: 34 protein-altering or splice-affecting, 14 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 14, Intron 3, Splice Site 2, 3'Flank 2, 5'UTR 1, Frame Shift Del 1, Splice Region 1, In Frame Del 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 154/298 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 27/191 reads (14%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.672+1_672+21del p.X224_splice | Splice Site (DEL) | VAF 77/403 reads (19%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ARHGAP22 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 57/263 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.47); catalogued as rs137922552, COSV50939280, COSV99984423; called by muse, mutect2, varscan2
- ARRDC5 | c.400G>A p.V134I (on ENST00000381781; = p.V120I on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/211 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.014); catalogued as rs150395951; called by muse, mutect2
- BACH2 | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs951978287; called by muse, mutect2, varscan2
- CA3 | c.352-8G>A | Splice Region (SNP) | VAF 25/114 reads (22%) | catalogued as COSV53410969; called by muse, mutect2, varscan2
- COL5A1 | c.4694C>T p.P1565L | Missense Mutation (SNP) | VAF 34/233 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV65674690; called by muse, mutect2, varscan2
- COLQ | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 36/466 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs763036328, CM122473; called by muse, mutect2
- FNDC11 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 14/197 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs906102568, COSV64442866; called by muse, mutect2
- GTF3C5 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs374887172; called by muse, mutect2, varscan2
- INPP5K | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as rs769608442, COSV57442024; called by muse, mutect2, varscan2
- INSRR | c.2102C>T p.P701L | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV63870745; called by muse, mutect2, varscan2
- KDM1A | c.757C>T p.H253Y | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.95); catalogued as COSV63088396; called by muse, mutect2, varscan2
- NEUROD1 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 42/264 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs146389992; called by muse, mutect2, varscan2
- PCK1 | c.257C>A p.A86D | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60130458; called by muse, mutect2, varscan2
- PLEK | c.380+1G>T p.X127_splice | Splice Site (SNP) | VAF 9/122 reads (7%) | catalogued as rs1308129633; called by muse, mutect2
- RGS6 | c.1376C>T p.S459L | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as rs1261035708, COSV59564231, COSV59577782; called by muse, mutect2, varscan2
- TENM1 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 14/187 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as COSV64430086; called by muse, mutect2
- ZNF185 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100248580; called by muse, mutect2
- ZNF648 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT tolerated (0.82); PolyPhen benign (0.024); catalogued as COSV100374352; called by muse, mutect2
- CAPN15 | c.2639T>C p.V880A | Missense Mutation (SNP) | VAF 53/450 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- FBXO39 | c.768C>G p.I256M | Missense Mutation (SNP) | VAF 80/306 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- FBXO47 | c.667C>T p.L223F | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- IQGAP1 | c.3187C>G p.R1063G | Missense Mutation (SNP) | VAF 15/203 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); called by muse, mutect2
- OR7A5 | c.503_505del p.F168del | In Frame Del (DEL) | VAF 52/370 reads (14%) | called by mutect2, pindel, varscan2
- PCLO | c.5128G>A p.D1710N | Missense Mutation (SNP) | VAF 30/306 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SETD2 | c.1120_1121del p.D374* | Frame Shift Del (DEL) | VAF 34/204 reads (17%) | called by pindel, varscan2
- SPIN3 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.717); called by muse, mutect2
- SPO11 | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- UBR4 | c.15484G>A p.A5162T | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- UHRF1 | c.1916C>A p.S639Y (on ENST00000612630 / NM_001290050.1; = p.S652Y on NM_013282.4) | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- VWDE | c.2051A>G p.H684R | Missense Mutation (SNP) | VAF 17/253 reads (7%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2
- XRCC4 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DACT2 | c.2214G>A p.G738= | Silent (SNP) | VAF 49/200 reads (25%) | called by muse, varscan2
- FAM83F | c.1179G>A p.L393= | Silent (SNP) | VAF 19/210 reads (9%) | called by muse, mutect2, varscan2
- GATA1 | c.294C>T p.Y98= | Silent (SNP) | VAF 12/299 reads (4%) | catalogued as COSV64961963; called by muse, mutect2
- GPR135 | c.459G>A p.A153= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as rs893381380; called by muse, mutect2
- MRTFA | c.2328A>G p.A776= | Silent (SNP) | VAF 14/83 reads (17%) | catalogued as rs1040374744; called by muse, mutect2, varscan2
- MUC5B | c.4131C>T p.D1377= | Silent (SNP) | VAF 16/276 reads (6%) | catalogued as rs780575337; called by muse, mutect2
- ORC4 | c.111A>C p.L37= | Silent (SNP) | VAF 13/113 reads (12%) | called by muse, mutect2, varscan2
- PCDHB13 | c.1959G>A p.S653= | Silent (SNP) | VAF 24/519 reads (5%) | catalogued as rs559738608; called by muse, mutect2
- PLXNB3 | c.4770C>T p.D1590= | Silent (SNP) | VAF 10/169 reads (6%) | catalogued as COSV100737735; called by muse, mutect2
- SLC9A7 | c.1197C>T p.N399= | Silent (SNP) | VAF 31/140 reads (22%) | called by muse, mutect2, varscan2
- THOC2 | c.681C>T p.F227= | Silent (SNP) | VAF 16/85 reads (19%) | called by muse, mutect2, varscan2
- TTC38 | c.810C>T p.A270= | Silent (SNP) | VAF 19/175 reads (11%) | catalogued as rs267606280, COSV66843616; called by muse, mutect2, varscan2
- UBAC1 | c.579C>T p.D193= | Silent (SNP) | VAF 16/176 reads (9%) | catalogued as rs547138493; called by muse, mutect2
- ZNF282 | c.1971C>T p.G657= | Silent (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2
- ACTR2 | c.-51C>T | 5'UTR (SNP) | VAF 4/24 reads (17%) | catalogued as rs760785080; called by mutect2, varscan2
- CCDC65 | chr12:48923615 T>C | 3'Flank (SNP) | VAF 9/252 reads (4%) | called by muse, mutect2
- FRMD8P1 | n.697G>A | RNA (SNP) | VAF 72/475 reads (15%) | called by muse, mutect2, varscan2
- NDUFA11 | chr19:5892985 del CC | 3'Flank (DEL) | VAF 6/59 reads (10%) | called by mutect2, pindel
- OXR1 | c.1627+78G>T | Intron (SNP) | VAF 16/151 reads (11%) | catalogued as rs561074289; called by muse, mutect2
- PNKD | c.236+1060C>T | Intron (SNP) | VAF 51/455 reads (11%) | called by muse, mutect2, varscan2
- RPL36A | c.301-14C>G | Intron (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- RPS19 | c.*36G>A | 3'UTR (SNP) | VAF 10/134 reads (7%) | catalogued as rs782801001; called by muse, mutect2
